MMRF case MMRF_1908 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/aa3aae0f-c433-486f-a48b-3dc341cf4ab4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.1 years (24,887 days); ISS stage: I; Days to last known disease status: 1,086 days (3.0 years); Days to last follow up: 1,086 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 123 days.
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 179 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 187 days; Days to treatment end: 188 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 190 days; Days to treatment end: 190 days.
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 387 days (1.1 years); Days to treatment end: 718 days (2.0 years).
   Treatment given: Therapeutic agents: Bendamustine + Bortezomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 983 days (2.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 180 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.558 mg/dL; Immunoglobulin G 4.33 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 2.6 µg/mL; Lactate Dehydrogenase 7.2 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 7.43 ×10⁹/L; Absolute Neutrophil 3.93 ×10⁹/L; Platelets 383 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.5 mmol/L; Albumin 51 g/L; Total Protein 7.1 g/dL; Glucose 5.12 mmol/L.
- Day 91 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 11.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.937 mg/dL; Lactate Dehydrogenase 7.52 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.24 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 375 ×10⁹/L; Creatinine 35.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.15 mmol/L; Albumin 42 g/L; Total Protein 6 g/dL; Glucose 3.91 mmol/L.
- Day 176 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.515 mg/dL; Immunoglobulin G 3.23 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 5.65 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5.17 ×10⁹/L; Absolute Neutrophil 2.37 ×10⁹/L; Platelets 324 ×10⁹/L; Creatinine 35.4 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 5.6 g/dL; Glucose 4.18 mmol/L.
- Day 255 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.736 mg/dL; Immunoglobulin G 3.24 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 8.34 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.37 ×10⁹/L; Absolute Neutrophil 2.43 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 37.1 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.25 mmol/L; Albumin 46 g/L; Total Protein 6.5 g/dL; Glucose 3.3 mmol/L.
- Day 351 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.963 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Lactate Dehydrogenase 4.78 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.69 ×10⁹/L; Absolute Neutrophil 4.58 ×10⁹/L; Platelets 316 ×10⁹/L; Creatinine 30.9 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 6.2 g/dL; Glucose 4.51 mmol/L.
- Day 460 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Lactate Dehydrogenase 6.95 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.94 ×10⁹/L; Absolute Neutrophil 1.18 ×10⁹/L; Platelets 281 ×10⁹/L; Creatinine 42.4 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 4.07 mmol/L.
- Day 530 (ECOG 1): Lactate Dehydrogenase 8 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.06 ×10⁹/L; Absolute Neutrophil 1.23 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 28.3 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 5.8 g/dL; Glucose 4.29 mmol/L.
- Day 640 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Lactate Dehydrogenase 5.45 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.29 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 334 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 4.51 mmol/L.
- Day 718 (ECOG 1): Lactate Dehydrogenase 5.1 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.61 ×10⁹/L; Absolute Neutrophil 1.54 ×10⁹/L; Platelets 329 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.53 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 4.35 mmol/L.
- Day 782: Lactate Dehydrogenase 5.2 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.38 ×10⁹/L; Absolute Neutrophil 2.57 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 41.5 µmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 5.06 mmol/L.
- Day 908 (ECOG 0): Lactate Dehydrogenase 8.17 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 8.27 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 48.6 µmol/L; Calcium 2.45 mmol/L; Albumin 48 g/L; Total Protein 7.1 g/dL; Glucose 4.9 mmol/L.
- Day 982: Hemoglobin 7.69 mmol/L; Leukocytes 18.1 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 256 ×10⁹/L; Creatinine 142 µmol/L; Calcium 4.03 mmol/L; Glucose 4.79 mmol/L.
- Day 1,086: Serum Free Immunoglobulin Light Chain, Kappa 2.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.092 mg/dL; Lactate Dehydrogenase 6.58 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.48 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 67.2 µmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 5.4 g/dL; Glucose 4.02 mmol/L.

Other clinical attributes
- Day -4: Weight: 58 kg; Height: 151 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1908_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_1908_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
